Somatic mutation profile of tumor specimen TCGA-VD-A8KI-01A (aliquot TCGA-VD-A8KI-01A-11D-A39W-08) from TCGA case TCGA-VD-A8KI, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.4 years (24,966 days).
Specimen TCGA-VD-A8KI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5932efd2-43b0-4a66-b9e0-ef73bb75ab9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8KI-10A (Blood Derived Normal), aliquot TCGA-VD-A8KI-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/719a7ff1-0a1a-4825-8b57-99a89efb82f5

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 14, Silent 6, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 26/76 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99680131; called by muse, mutect2, varscan2
- GNAQ | c.142G>T p.G48* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | hotspot (GDC flag); called by muse, mutect2, varscan2
- C4orf17 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as rs201530498; called by muse, mutect2, varscan2
- FOXF2 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1345129732; called by muse, mutect2, varscan2
- MAPKBP1 | c.4522C>T p.R1508W (on ENST00000456763 / NM_001128608.2; = p.R1502W on NM_014994.3) | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs533499391; called by muse, varscan2
- SQSTM1 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs753313263; called by muse, mutect2, varscan2
- ATP1B4 | c.1052T>C p.F351S (on ENST00000218008 / NM_001142447.3; = p.F347S on NM_012069.5) | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRCA2 | c.8514A>T p.L2838F | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); called by muse, varscan2
- BRCA2 | c.8521_8531del p.F2841Kfs*24 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | called by pindel, varscan2
- C1orf94 | c.727T>C p.F243L (on ENST00000488417 / NM_001134734.2; = p.F53L on NM_032884.5) | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CCNG2 | c.25_66del p.L9_N22del | In Frame Del (DEL) | VAF 20/91 reads (22%) | called by mutect2, pindel
- IL18R1 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.191); called by muse, mutect2
- KIAA1109 | c.14186C>G p.A4729G | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCAM1 | c.1304C>T p.T435I (on ENST00000316851 / NM_181351.5; = p.T425I on NM_000615.7) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NOD2 | c.2836G>A p.A946T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTBP2 | c.1573C>G p.L525V (on ENST00000426398 / NM_001300986.2; = p.L516V on NM_021190.4) | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SULF2 | c.1631T>A p.V544E | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- BZW2 | c.351A>G p.K117= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1441747313; called by muse, mutect2, varscan2
- FAAP20 | c.315C>T p.H105= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs772593583, COSV101052041; called by muse, mutect2, varscan2
- FANCA | c.96G>A p.R32= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs1381349863; called by muse, mutect2, varscan2
- HEPN1 | c.261A>G p.L87= | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- HOXA4 | c.948T>A p.V316= | Silent (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- STYXL1 | c.843C>T p.N281= | Silent (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
